Gene-level copy-number profile of tumor specimen ALCH-B3IN-TTP1-A from ALCHEMIST case ALCH-B3IN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.5 years (25,765 days).
Specimen ALCH-B3IN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dd2dacb0-98f7-488e-9031-9f45a14f3d19.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3IN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/5783a711-e1a2-40d3-ba2e-79ae1cc7220a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 461; copy number 2: 55,709; copy number 3: 2,214; copy number 4: 2; copy number 11: 3; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,581,560–2,591,469, 2 genes (within-gene range 0–2): AL139246.3, PRXL2B.
- chr8:143,915,153–143,976,734, 2 genes: PLEC, MIR661.
- chr16:2,106,669–2,113,342, 2 genes (within-gene range 0–2): MIR6511B1, AC009065.6.
- chr16:89,919,165–89,936,092, 2 genes (within-gene range 0–2): AC092143.1, AC092143.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:43,107,942–43,168,646, 1 gene, copy number 13 (within-gene range 2–13): AP001631.2.
- chr21:43,159,066–43,162,277, 1 gene, copy number 13: AP001631.1.
- chr21:44,217,014–44,244,993, 3 genes, copy number 11: ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 460. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
